TCGA case TCGA-09-2045 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3768d34f-1527-40db-b116-cd80cee5ec3a

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Dead; Days to death: 1,069 days (2.9 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 50.1 years (18,285 days); Year of diagnosis: 1996; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G2; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: 1-10 mm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 11 days; Days to treatment end: 11 days; Number of cycles: 1; Treatment dose: 810 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 11 days; Days to treatment end: 11 days; Number of cycles: 1; Treatment dose: 135 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 64 days; Days to treatment end: 94 days; Number of cycles: 2; Treatment dose: 50 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 64 days; Days to treatment end: 94 days; Number of cycles: 2; Treatment dose: 100 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 121 days; Days to treatment end: 239 days; Number of cycles: 5; Treatment dose: 50 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 121 days; Days to treatment end: 239 days; Number of cycles: 5; Treatment dose: 135 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 678 days (1.9 years); Days to treatment end: 808 days (2.2 years); Number of cycles: 6; Treatment dose: 70 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 678 days (1.9 years); Days to treatment end: 808 days (2.2 years); Number of cycles: 6; Treatment dose: 1 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 875 days (2.4 years); Days to treatment end: 895 days (2.5 years); Number of cycles: 2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 933 days (2.6 years); Days to treatment end: 939 days (2.6 years); Number of cycles: 2; Treatment dose: 560 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 933 days (2.6 years); Days to treatment end: 939 days (2.6 years); Number of cycles: 2; Treatment dose: 1,600 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 51.8 years (18,916 days); Days to diagnosis: 631 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 631 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 631 days (1.7 years); Evidence of recurrence type: Physical Examination.
- Days to follow up: 1,069 days (2.9 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-09-2045-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-09-2045-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-09-2045-01A-01-BS1: Section location: Bottom; Percent tumor cells: 94; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 5.
- Sample TCGA-09-2045-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.5; Intermediate dimension: 0.4; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Cisplatinum.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxotere; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Recurrent and progression.
- Drug treatment 6: Therapy regimen: Progression.
- Drug treatment 6, Route of administrations: Route of administration: PO.
- Drug treatment 9: Pharmaceutical therapy drug name: Gemcitibine; Therapy regimen: Progression.
- Drug treatment 10: Pharmaceutical therapy drug name: Toptecan; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Recurrent and progression.
- Drug treatment 11: Pharmaceutical therapy drug name: Carboplatinum; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Stable Disease; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,069 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,069 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 631 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-09-2045-01): tumor purity 0.92, ploidy 2.05, whole-genome doublings 0 (call status: legacy_call).
